Somatic mutation profile of tumor specimen 1ea1d7ee-e382-4a68-8e7c-74e833 (aliquot 1ea1d7ee-e382-4a68-8e7c-74e833_D6_2) from CPTAC case 09CO014, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 1ea1d7ee-e382-4a68-8e7c-74e833: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 273fa268-247d-432b-b5b1-feb874062d6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen d97af421-cedf-4cc6-b1e5-3b1ad2 (Blood Derived Normal), aliquot d97af421-cedf-4cc6-b1e5-3b1ad2_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35002653-4277-4b75-845e-7a21c41a8624

The open-access MAF lists 306 somatic variants for this specimen: 202 protein-altering or splice-affecting, 62 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 170, Silent 62, Intron 22, Nonsense Mutation 20, 3'UTR 7, 5'UTR 6, Splice Region 5, RNA 4, Frame Shift Ins 3, Frame Shift Del 2, 5'Flank 2, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 55/121 reads (45%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CP | c.2253G>A p.W751* | Nonsense Mutation (SNP) | VAF 36/132 reads (27%) | catalogued as rs1559940237; ClinVar: pathogenic; called by muse, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 37/109 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 133/313 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABHD5 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs1461389889; called by muse, varscan2
- ADAMTS7 | c.4918C>T p.R1640C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs765492663; called by muse, mutect2, varscan2
- ADGRV1 | c.2248G>A p.V750M | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as rs780802447; called by muse, mutect2, varscan2
- AGO3 | c.1593G>A p.A531= | Splice Region (SNP) | VAF 14/44 reads (32%) | catalogued as COSV99869584; called by muse, mutect2
- AGT | c.1042C>T p.H348Y | Missense Mutation (SNP) | VAF 86/668 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.452); catalogued as rs777162288; called by muse, mutect2, varscan2
- AMER1 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 134/194 reads (69%) | catalogued as COSV57655167; called by muse, mutect2, varscan2
- ANKRD36B | c.2849G>A p.R950H | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs200057888; called by mutect2, varscan2
- ARHGAP33 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 64/352 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs755068272; called by muse, mutect2, varscan2
- BARD1 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV53616210; called by muse, mutect2
- BCL9L | c.1225C>T p.R409W | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1295612684, COSV52681688; called by muse, mutect2, varscan2
- CAMK4 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs374581815, COSV56670305; called by muse, mutect2, varscan2
- CAPN10 | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs146771809; called by muse, mutect2, varscan2
- CCDC185 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as rs138334475; called by muse, mutect2, varscan2
- CELF2 | c.419C>T p.S140L (on ENST00000416382 / NM_001025077.3; = p.S147L on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs746403544, COSV59971344; called by muse, mutect2, varscan2
- CHD3 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as rs149936335; called by muse, mutect2, varscan2
- CLDN10 | c.28G>C p.V10L | Missense Mutation (SNP) | VAF 41/310 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs150191933; called by muse, mutect2, varscan2
- COL1A2 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV51955505; called by muse, mutect2, varscan2
- COL6A6 | c.3202G>A p.E1068K | Missense Mutation (SNP) | VAF 90/264 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV62037037; called by muse, mutect2, varscan2
- CORIN | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769638775, COSV56699677; called by muse, mutect2, varscan2
- DAPK1 | c.503T>G p.I168S | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778438856; called by muse, mutect2, varscan2
- DAZAP1 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs930713428; called by muse, mutect2, varscan2
- DCLK1 | c.2048C>A p.S683Y | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV55211382; called by muse, mutect2, varscan2
- DIDO1 | c.6661G>A p.A2221T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.001); catalogued as rs201786226, COSV99827256; called by muse, mutect2, varscan2
- ERV3-1 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs375141300; called by muse, mutect2, varscan2
- FAM221B | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 116/260 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs774683145; called by muse, mutect2, varscan2
- FCGR2A | c.197G>A p.R66H (on ENST00000271450 / NM_001136219.3; = p.R65H on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/502 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750989159, COSV54838318; called by muse, mutect2, varscan2
- GABBR2 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs772244503; ClinVar: benign; called by muse, mutect2, varscan2
- GDF10 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs782386699; called by muse, mutect2, varscan2
- GRIN3A | c.1247C>T p.T416M | Missense Mutation (SNP) | VAF 63/304 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as rs764843723; called by muse, mutect2, varscan2
- GSX1 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as rs1225656303; called by muse, mutect2
- HAX1 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 128/346 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs200890522; called by muse, mutect2, varscan2
- HEATR5B | c.2732G>A p.G911D | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99250450; called by muse, mutect2, varscan2
- KCNK5 | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 74/142 reads (52%) | catalogued as COSV63989465; called by muse, varscan2
- KIR2DL4 | c.277C>T p.R93C (on ENST00000396284; = p.R54C on NM_001080770.2) | Missense Mutation (SNP) | VAF 83/409 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs758111394, COSV100610563, COSV60877040, COSV60879620; called by muse, mutect2, varscan2
- KLKB1 | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 25/277 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146525902; called by muse, mutect2
- KNDC1 | c.2645C>A p.S882* | Nonsense Mutation (SNP) | VAF 19/108 reads (18%) | catalogued as COSV58834000; called by muse, mutect2, varscan2
- KRTAP13-4 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 59/302 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs542055849, COSV100481756; called by muse, mutect2, varscan2
- LEF1 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1359509909, COSV54465851; called by muse, mutect2, varscan2
- LIAS | c.281C>T p.P94L (on ENST00000261434 / NM_001363700.2; = p.T125= on NM_006859.4) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.856); catalogued as rs538035764; called by muse, mutect2, varscan2
- LIFR | c.1390T>G p.F464V | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs984558184; called by muse, mutect2, varscan2
- LRIF1 | c.1520T>C p.I507T | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.354); catalogued as rs1325468836; called by muse, mutect2
- MALRD1 | c.5078G>A p.R1693Q | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs908498078; called by muse, mutect2
- MALSU1 | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1284030972; called by muse, mutect2, varscan2
- MMRN1 | c.3053C>T p.T1018M | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs746029068; called by muse, mutect2, varscan2
- MPLKIP | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs926238318; called by muse, mutect2, varscan2
- MUC16 | c.36773T>A p.M12258K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV67477830; called by muse, mutect2, varscan2
- MXI1 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1326783253; called by muse, mutect2, varscan2
- MYO18B | c.7148G>A p.R2383Q | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.933); catalogued as rs768235451, COSV59129934; called by muse, mutect2, varscan2
- NPAP1 | c.841C>A p.L281M | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.824); catalogued as COSV61508323; called by muse, mutect2, varscan2
- OR10X1 | c.814T>C p.S272P | Missense Mutation (SNP) | VAF 116/340 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs369289646; called by muse, mutect2, varscan2
- PCDHA3 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65364216; called by muse, mutect2, varscan2
- PCDHGA7 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 45/319 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.15); catalogued as COSV99532790; called by muse, mutect2, varscan2
- PCYOX1L | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 71/516 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs757459631; called by muse, mutect2, varscan2
- PLAAT5 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.14); catalogued as rs1451443554; called by muse, mutect2, varscan2
- PNCK | c.931C>T p.R311W (on ENST00000340888 / NM_001366975.1; = p.R394W on NM_001039582.3) | Missense Mutation (SNP) | VAF 155/233 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs781926333; called by muse, mutect2, varscan2
- PPP1R10 | c.1361A>C p.N454T | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV64739093; called by muse, mutect2
- PRRC2C | c.4055G>A p.R1352H (on ENST00000367742; = p.R1350H on NM_015172.4) | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs142373462; called by muse, mutect2, varscan2
- RTP2 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 131/357 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs754331122, COSV64079023; called by muse, mutect2, varscan2
- RYR1 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 64/348 reads (18%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.97); catalogued as rs727504129, CM152875, COSV62091125; ClinVar: uncertain significance; called by mutect2, varscan2
- SACS | c.2183G>T p.R728L | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as rs764645953; called by muse, mutect2, varscan2
- SCAP | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as rs745402503, COSV55559168; called by muse, mutect2, varscan2
- SCLY | c.1004G>A p.R335H (on ENST00000651534; = p.R327H on NM_016510.7) | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs763936839; called by muse, mutect2, varscan2
- SCN7A | c.4558C>T p.Q1520* | Nonsense Mutation (SNP) | VAF 18/156 reads (12%) | catalogued as rs1250326635; called by muse, mutect2, varscan2
- SEMA6C | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.053); catalogued as rs1175074705; called by muse, mutect2, varscan2
- SETD1A | c.2398C>A p.Q800K | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.041); catalogued as COSV99353335; called by muse, mutect2, varscan2
- SH3TC2 | c.115A>G p.K39E | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as rs1183623139; called by muse, mutect2
- SLC26A5 | c.2065C>T p.R689W | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs776378925, COSV59706662; called by muse, mutect2, varscan2
- SLC2A6 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866657019; called by muse, mutect2, varscan2
- SLC44A5 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs373084017; called by muse, mutect2, varscan2
- SPTAN1 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.896); catalogued as COSV63990715; called by muse, mutect2, varscan2
- SRM | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs760013087; called by muse, mutect2, varscan2
- TARS2 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1213437290; called by muse, mutect2, varscan2
- TET1 | c.6074G>A p.R2025Q | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1467264884, COSV65383659; called by muse, mutect2, varscan2
- TNFSF13B | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV65516638; called by muse, mutect2, varscan2
- TPRG1 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777616187; called by muse, mutect2, varscan2
- TRAPPC9 | c.2912G>A p.R971Q | Missense Mutation (SNP) | VAF 124/228 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs750526802; called by muse, mutect2, varscan2
- TRNT1 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1012537748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSHZ2 | c.1398A>C p.K466N | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV61588681, COSV61589886; called by muse, mutect2, varscan2
- TTN | c.52853C>T p.A17618V (on ENST00000591111; = p.A10194V on NM_003319.4) | Missense Mutation (SNP) | VAF 46/153 reads (30%) | PolyPhen probably damaging (0.997); catalogued as rs868535712; called by muse, mutect2, varscan2
- TTN | c.43666C>T p.R14556C (on ENST00000591111; = p.R7132C on NM_003319.4) | Missense Mutation (SNP) | VAF 39/128 reads (30%) | PolyPhen probably damaging (0.998); catalogued as rs748917057, COSV100632458; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- UNC13A | c.2317C>T p.R773W | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53201796; called by muse, mutect2, varscan2
- VLDLR | c.2297C>T p.T766I | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs1253837536; called by muse, mutect2
- VPS54 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs770503214; called by muse, mutect2, varscan2
- ZNF462 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.381); catalogued as rs1424148388; called by muse, mutect2, varscan2
- ZNF518B | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 78/291 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs769394798, COSV58722884; called by muse, mutect2, varscan2
- ZNF710 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs772268271; called by muse, mutect2, varscan2
- ZNF746 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 116/437 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs751170528; called by muse, mutect2, varscan2
- ZNF880 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV100690258, COSV59814345; called by muse, mutect2, varscan2
- AC098582.1 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 26/117 reads (22%) | called by muse, mutect2, varscan2
- ADAM17 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADCY2 | c.2505G>C p.K835N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ADGRA3 | c.2053C>T p.P685S | Missense Mutation (SNP) | VAF 72/278 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- AHNAK | c.15277G>T p.V5093L | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ANK3 | c.1636G>A p.D546N | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- ARHGAP9 | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ARNT | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ARNT | c.24C>T p.P8= | Splice Region (SNP) | VAF 35/64 reads (55%) | called by muse, mutect2, varscan2
- ARPC2 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ASIC3 | c.440C>A p.A147E | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ATOH1 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 47/311 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATPAF2 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 99/219 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- B3GNT5 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2, varscan2
- BBS2 | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- BMP10 | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 97/381 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- BTBD11 | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.012); called by mutect2, varscan2
- C1GALT1 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 50/152 reads (33%) | called by muse, mutect2, varscan2
- C4BPA | c.200C>G p.T67S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- C6orf132 | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 60/106 reads (57%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- CATSPERB | c.1805C>T p.S602F | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CBFA2T2 | c.1607G>T p.W536L | Missense Mutation (SNP) | VAF 41/341 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC15 | c.236C>A p.A79D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- CCDC168 | c.11237A>C p.K3746T | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CDC27 | c.1690A>G p.K564E | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- CLDN5 | c.187C>A p.Q63K (on ENST00000618236 / NM_001363066.2; = p.Q148K on NM_003277.4) | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CLSTN3 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CNGA4 | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 92/295 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CNTNAP3 | c.1553C>T p.T518I | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CORO1C | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CPA3 | c.1242G>T p.K414N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DLX3 | c.326-5C>T | Splice Region (SNP) | VAF 20/117 reads (17%) | called by muse, mutect2, varscan2
- DLX3 | c.326-6C>T | Splice Region (SNP) | VAF 20/116 reads (17%) | called by muse, mutect2, varscan2
- DOP1A | c.4294G>A p.G1432S | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ECH1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ECM1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 49/213 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ECM1 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ERCC8 | c.1018G>A p.V340I (on ENST00000265038; = p.V321I on NM_000082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EVPL | c.5347dup p.E1783Gfs*40 | Frame Shift Ins (INS) | VAF 69/253 reads (27%) | called by mutect2, pindel, varscan2
- FAM189A1 | c.503C>A p.A168D | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- FBXO4 | c.750G>T p.E250D | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- GAB4 | c.1258G>T p.V420F | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- HEATR5A | c.382A>G p.R128G | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HKDC1 | c.1970C>T p.T657I | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNRNPUL1 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- HSPB8 | c.401T>C p.I134T | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); called by muse, mutect2
- ICAM5 | c.1345G>A p.G449R | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- IFRD2 | c.9G>A p.W3* | Nonsense Mutation (SNP) | VAF 32/198 reads (16%) | called by muse, mutect2, varscan2
- IFRD2 | c.8G>A p.W3* | Nonsense Mutation (SNP) | VAF 30/194 reads (15%) | called by muse, mutect2, varscan2
- IGF2R | c.1116G>T p.Q372H | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- IGSF9 | c.2314C>T p.R772C (on ENST00000368094 / NM_001135050.2; = p.R756C on NM_020789.4) | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- IL18RAP | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- ITGA8 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAV | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- IVNS1ABP | c.965G>T p.S322I | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- KIAA0825 | c.1393C>T p.Q465* | Nonsense Mutation (SNP) | VAF 65/182 reads (36%) | called by muse, mutect2, varscan2
- LRRC45 | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC8C | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LTBR | c.801+5T>G | Splice Region (SNP) | VAF 34/197 reads (17%) | called by muse, mutect2, varscan2
- MAP3K5 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 85/141 reads (60%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- MATN3 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- MYH15 | c.5635C>T p.Q1879* | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- NADK | c.1156_1157del p.K386Efs*33 | Frame Shift Del (DEL) | VAF 15/123 reads (12%) | called by mutect2, pindel, varscan2
- NBPF11 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 103/325 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- NHSL2 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NOL6 | c.449G>A p.G150D | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOS1AP | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 87/215 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PAICS | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PASD1 | c.638A>T p.Q213L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, varscan2
- PBRM1 | c.773dup p.N258Kfs*6 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2
- PCDHB4 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 127/900 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHB5 | c.2292G>C p.K764N | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PCDHGA10 | c.1155G>T p.Q385H | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PDE3B | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 43/121 reads (36%) | called by muse, mutect2, varscan2
- PPIC | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 70/145 reads (48%) | called by muse, mutect2, varscan2
- PSD3 | c.1312A>G p.T438A | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- PTCH1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RAPGEF1 | c.1304G>C p.G435A | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RELCH | c.775C>G p.L259V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- RLF | c.2023G>T p.G675C | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF157 | c.1358G>T p.C453F | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SARDH | c.296A>G p.E99G | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SBNO1 | c.1469G>T p.R490L (on ENST00000420886; = p.R489L on NM_018183.5) | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SORCS3 | c.2448C>G p.C816W | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SPATA31A1 | c.3142A>T p.N1048Y | Missense Mutation (SNP) | VAF 73/434 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TARBP1 | c.3589C>T p.Q1197* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- TMEM184A | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 7/200 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- TNKS2 | c.710T>A p.V237D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC22 | c.210C>G p.H70Q | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TTN | c.81264T>A p.N27088K (on ENST00000591111; = p.N19664K on NM_003319.4) | Missense Mutation (SNP) | VAF 22/383 reads (6%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- TULP1 | c.948G>A p.M316I | Missense Mutation (SNP) | VAF 184/352 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TUT4 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- UNC5B | c.1197C>G p.Y399* | Nonsense Mutation (SNP) | VAF 30/150 reads (20%) | called by muse, mutect2, varscan2
- USF3 | c.4705C>T p.H1569Y | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- UTP20 | c.4038dup p.E1347Rfs*21 | Frame Shift Ins (INS) | VAF 18/62 reads (29%) | called by mutect2, pindel, varscan2
- VPS54 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VSIG8 | c.1025C>T p.T342I | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- WDFY3 | c.7225G>A p.E2409K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.007); called by muse, mutect2
- XDH | c.3142G>T p.V1048F | Missense Mutation (SNP) | VAF 79/186 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by mutect2, varscan2
- XPO6 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- YOD1 | c.5T>A p.F2Y | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZBTB44 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- ZCCHC4 | c.1037A>G p.Y346C | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZDBF2 | c.2111C>A p.S704Y | Missense Mutation (SNP) | VAF 31/267 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- ZFR | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ZNF343 | c.579C>A p.F193L | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF513 | c.942del p.W314* | Frame Shift Del (DEL) | VAF 142/518 reads (27%) | called by mutect2, pindel, varscan2
- ZNF717 | c.2349G>T p.E783D | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.813); called by mutect2, varscan2
- ATP13A5 | c.1944G>A p.R648= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as rs977365136, COSV100665113; called by muse, mutect2, varscan2
- ATP5F1C | c.21C>T p.V7= | Silent (SNP) | VAF 26/174 reads (15%) | catalogued as rs758991568; called by muse, mutect2, varscan2
- BAHCC1 | c.663C>A p.G221= | Silent (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- C1GALT1C1 | c.441G>A p.T147= | Silent (SNP) | VAF 106/145 reads (73%) | catalogued as rs186603233; called by muse, mutect2, varscan2
- CFAP69 | c.2535C>T p.N845= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs558288448, COSV60184206; called by muse, mutect2, varscan2
- CILP2 | c.2232C>T p.Y744= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as rs1406277815, COSV99365134; called by muse, mutect2, varscan2
- CLDN7 | c.108G>A p.A36= | Silent (SNP) | VAF 46/115 reads (40%) | catalogued as rs1283830501; called by muse, mutect2, varscan2
- COL3A1 | c.1737C>T p.G579= | Silent (SNP) | VAF 18/428 reads (4%) | called by muse, mutect2
- COL4A1 | c.1929T>A p.P643= | Silent (SNP) | VAF 60/516 reads (12%) | called by muse, mutect2, varscan2
- COL6A3 | c.966C>T p.I322= | Silent (SNP) | VAF 110/393 reads (28%) | catalogued as rs369160080; called by muse, mutect2, varscan2
- COL9A1 | c.903G>A p.P301= | Silent (SNP) | VAF 180/318 reads (57%) | catalogued as rs267601106, COSV57889774; called by muse, mutect2, varscan2
- COMT | c.42G>A p.L14= | Silent (SNP) | VAF 69/302 reads (23%) | called by muse, mutect2, varscan2
- CPXM2 | c.789C>T p.P263= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs141382056, COSV99582808; called by muse, mutect2, varscan2
- DHX34 | c.2547C>T p.P849= | Silent (SNP) | VAF 58/198 reads (29%) | catalogued as rs1057000349; called by muse, mutect2, varscan2
- DLG5 | c.5025C>T p.S1675= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs758222263, COSV100967393; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.462G>A p.S154= | Silent (SNP) | VAF 56/242 reads (23%) | catalogued as rs142311304; called by muse, mutect2, varscan2
- EHHADH | c.741G>A p.V247= | Silent (SNP) | VAF 32/208 reads (15%) | catalogued as rs373788163; called by muse, mutect2, varscan2
- EPHA5 | c.1137G>T p.P379= | Silent (SNP) | VAF 72/212 reads (34%) | catalogued as rs747980985, COSV56654107, COSV56669678; called by mutect2, varscan2
- ERBB2 | c.1632C>T p.C544= | Silent (SNP) | VAF 71/162 reads (44%) | catalogued as rs775678910, COSV54073880; called by muse, mutect2, varscan2
- FAM186A | c.87C>T p.P29= | Silent (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- FCRL1 | c.954T>G p.G318= | Silent (SNP) | VAF 24/256 reads (9%) | catalogued as COSV100839828; called by muse, mutect2
- FGF13 | c.117G>A p.A39= | Silent (SNP) | VAF 59/91 reads (65%) | catalogued as rs768993513, COSV65436054; called by muse, mutect2, varscan2
- FREM2 | c.1605C>T p.R535= | Silent (SNP) | VAF 100/384 reads (26%) | catalogued as rs760843477; called by muse, mutect2, varscan2
- GART | c.993C>T p.N331= | Silent (SNP) | VAF 21/91 reads (23%) | called by muse, mutect2, varscan2
- GAS6 | c.1596C>T p.A532= | Silent (SNP) | VAF 49/203 reads (24%) | catalogued as rs201938938, COSV59849807; called by muse, mutect2, varscan2
- HSPA4 | c.1074C>T p.F358= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as rs201494139; called by muse, mutect2
- IFITM1 | c.243C>T p.T81= | Silent (SNP) | VAF 52/183 reads (28%) | catalogued as rs1054925265, COSV60249593; called by muse, varscan2
- IRS1 | c.1506G>A p.T502= | Silent (SNP) | VAF 109/376 reads (29%) | catalogued as rs777028285, COSV59338805; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.180C>T p.H60= | Silent (SNP) | VAF 91/249 reads (37%) | called by muse, mutect2, varscan2
- KIF12 | c.534G>A p.G178= (on ENST00000640217; = p.G40= on NM_138424.1) | Silent (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- LRRC66 | c.1962C>T p.S654= | Silent (SNP) | VAF 82/275 reads (30%) | catalogued as rs201216051; called by muse, mutect2, varscan2
- MAB21L1 | c.903C>T p.N301= | Silent (SNP) | VAF 40/328 reads (12%) | catalogued as COSV59765829; called by muse, mutect2, varscan2
- MTNR1B | c.132C>T p.S44= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as rs1325543586; called by muse, mutect2, varscan2
- MUC2 | c.924C>T p.C308= | Silent (SNP) | VAF 70/255 reads (27%) | catalogued as rs751749267; called by muse, mutect2, varscan2
- NBPF11 | c.819G>A p.V273= | Silent (SNP) | VAF 102/318 reads (32%) | called by muse, mutect2, varscan2
- NEB | c.12471G>A p.T4157= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs780714195; ClinVar: likely benign; called by muse, mutect2, varscan2
- NFKBIZ | c.1572C>A p.G524= | Silent (SNP) | VAF 16/111 reads (14%) | called by mutect2, varscan2
- OR5AK2 | c.861T>C p.P287= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as rs774580162; called by muse, mutect2, varscan2
- PBLD | c.711C>T p.L237= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV53266771, COSV99515987; called by muse, mutect2, varscan2
- PCDH7 | c.822C>T p.Y274= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV62338579; called by muse, mutect2
- PCDHA13 | c.867G>A p.V289= | Silent (SNP) | VAF 81/335 reads (24%) | called by muse, mutect2, varscan2
- PCDHA3 | c.330G>A p.V110= | Silent (SNP) | VAF 46/330 reads (14%) | catalogued as rs1562179621; called by muse, mutect2, varscan2
- PCDHB11 | c.297C>A p.I99= | Silent (SNP) | VAF 18/428 reads (4%) | called by muse, mutect2
- PCDHGA3 | c.243C>T p.S81= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as rs143610564; called by muse, mutect2, varscan2
- PLG | c.1050G>A p.P350= | Silent (SNP) | VAF 112/190 reads (59%) | catalogued as rs775045516, COSV51981589; called by muse, mutect2, varscan2
- POM121L12 | c.684C>A p.S228= | Silent (SNP) | VAF 48/348 reads (14%) | catalogued as COSV68692170, COSV68694065; called by muse, mutect2, varscan2
- PTGIR | c.147C>T p.F49= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as rs577122089; called by muse, mutect2, varscan2
- RGS3 | c.1137C>T p.V379= (on ENST00000350696 / NM_001282923.2; = p.V267= on NM_017790.4) | Silent (SNP) | VAF 51/214 reads (24%) | called by muse, varscan2
- RHOBTB1 | c.567C>T p.S189= | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as rs1463708797; called by muse, mutect2, varscan2
- S1PR5 | c.996G>A p.P332= | Silent (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- SARDH | c.1461G>C p.P487= | Silent (SNP) | VAF 16/111 reads (14%) | called by muse, mutect2, varscan2
- SARDH | c.537C>T p.S179= | Silent (SNP) | VAF 22/98 reads (22%) | called by muse, mutect2, varscan2
- SDK1 | c.5607C>T p.L1869= | Silent (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- SLC27A4 | c.1380C>T p.F460= | Silent (SNP) | VAF 43/192 reads (22%) | catalogued as rs773449802; called by muse, mutect2, varscan2
- SRGAP2 | c.2286C>T p.D762= (on ENST00000624873 / NM_001170637.4; = p.D763= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs782083195; called by muse, mutect2, varscan2
- TCERG1 | c.987G>A p.V329= | Silent (SNP) | VAF 43/154 reads (28%) | called by muse, mutect2, varscan2
- TENM3 | c.6768C>T p.P2256= | Silent (SNP) | VAF 85/334 reads (25%) | catalogued as rs747026270; called by muse, mutect2, varscan2
- TF | c.456C>A p.G152= | Silent (SNP) | VAF 107/337 reads (32%) | called by muse, mutect2, varscan2
- USP4 | c.495C>T p.I165= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs564412761, COSV55536353; called by muse, mutect2, varscan2
- VPS13A | c.8673C>T p.A2891= | Silent (SNP) | VAF 25/179 reads (14%) | called by muse, mutect2, varscan2
- WDR44 | c.354G>A p.P118= | Silent (SNP) | VAF 84/136 reads (62%) | catalogued as rs772571309, COSV54164020; called by muse, mutect2, varscan2
- ZBTB10 | c.549C>T p.S183= | Silent (SNP) | VAF 34/60 reads (57%) | catalogued as rs1211517862; called by muse, mutect2, varscan2
- AGAP12P | n.1826C>A | RNA (SNP) | VAF 66/762 reads (9%) | called by muse, mutect2
- ANKRD30B | c.2313+1553C>G | Intron (SNP) | VAF 16/41 reads (39%) | catalogued as rs1440530528; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+1527G>T | Intron (SNP) | VAF 34/461 reads (7%) | catalogued as rs782594769; called by muse, mutect2
- ARMH1 | c.921-25G>A | Intron (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- BTD | c.-386A>T | 5'UTR (SNP) | VAF 53/283 reads (19%) | called by muse, mutect2, varscan2
- C5orf38 | c.*258C>T | 3'UTR (SNP) | VAF 21/37 reads (57%) | catalogued as rs1258483313; called by muse, mutect2, varscan2
- CBFA2T2 | c.-4G>A | 5'UTR (SNP) | VAF 21/69 reads (30%) | catalogued as rs749796013, COSV60074240; called by muse, mutect2, varscan2
- CNN2 | c.654+396A>G | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- CTSA | c.357+21G>A | Intron (SNP) | VAF 145/473 reads (31%) | called by muse, mutect2, varscan2
- DDC | c.315+30G>T | Intron (SNP) | VAF 65/461 reads (14%) | called by muse, mutect2, varscan2
- DNAAF3 | c.-67C>T | 5'UTR (SNP) | VAF 23/99 reads (23%) | called by muse, mutect2, varscan2
- EFHC1 | c.*2196C>G | 3'UTR (SNP) | VAF 22/501 reads (4%) | called by muse, mutect2
- FAM153CP | n.201-2288G>A | Intron (SNP) | VAF 19/151 reads (13%) | catalogued as rs755066481, COSV67752890; called by muse, mutect2, varscan2
- FOXC2 | c.*24del | 3'UTR (DEL) | VAF 25/127 reads (20%) | catalogued as rs748341504; called by mutect2, pindel, varscan2
- GP6 | c.*69C>T | 3'UTR (SNP) | VAF 92/330 reads (28%) | catalogued as rs373596955; called by muse, mutect2, varscan2
- HACE1 | c.1075-13_1075-12del | Intron (DEL) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- KRT17 | c.1204+34_1204+40del | Intron (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- KYAT1 | c.1122+40C>T | Intron (SNP) | VAF 29/150 reads (19%) | called by muse, mutect2, varscan2
- LINC00574 | n.314C>T | RNA (SNP) | VAF 114/216 reads (53%) | called by muse, mutect2, varscan2
- MASP1 | c.1304-5482A>T | Intron (SNP) | VAF 49/300 reads (16%) | called by muse, mutect2, varscan2
- MCM3AP | chr21:46230525 C>T | 3'Flank (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- MIA | c.*30C>T | 3'UTR (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- MIA | c.*31C>T | 3'UTR (SNP) | VAF 14/64 reads (22%) | catalogued as rs1025399590; called by muse, mutect2, varscan2
- MYPN | c.*1422C>A | 3'UTR (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2
- NBL1 | chr1:19643329 G>A | 5'Flank (SNP) | VAF 17/96 reads (18%) | catalogued as rs552896981; called by muse, mutect2, varscan2
- NPAT | c.-10G>A | 5'UTR (SNP) | VAF 13/66 reads (20%) | catalogued as rs1166880807; called by muse, mutect2, varscan2
- PIGG | c.-18C>T | 5'UTR (SNP) | VAF 23/91 reads (25%) | called by muse, mutect2, varscan2
- PRKRA | c.65+62G>A | Intron (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- RACK1 | chr5:181247301 G>A | 5'Flank (SNP) | VAF 48/140 reads (34%) | called by muse, mutect2, varscan2
- RASA4CP | n.55G>A | RNA (SNP) | VAF 64/215 reads (30%) | called by muse, mutect2, varscan2
- RGS3 | c.3081-274G>A | Intron (SNP) | VAF 46/233 reads (20%) | catalogued as rs747060935, COSV100636516; called by muse, mutect2, varscan2
- RPF1 | c.-1C>T | 5'UTR (SNP) | VAF 7/31 reads (23%) | catalogued as rs1164449946; called by muse, mutect2
- SLC2A11 | c.21+1119C>T | Intron (SNP) | VAF 42/193 reads (22%) | called by muse, mutect2, varscan2
- SLIT2 | c.1463-587G>A | Intron (SNP) | VAF 41/144 reads (28%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.1625C>T | RNA (SNP) | VAF 88/468 reads (19%) | called by muse, mutect2, varscan2
- SPOCD1 | c.1869-178T>C | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- TMEM191C | c.472-50C>G | Intron (SNP) | VAF 12/278 reads (4%) | catalogued as rs1427666962; called by muse, mutect2
- TRAPPC2L | c.33+32C>T | Intron (SNP) | VAF 12/51 reads (24%) | catalogued as rs375967968; called by muse, mutect2, varscan2
- TTC3 | c.845+1297G>A | Intron (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23471C>T | Intron (SNP) | VAF 18/226 reads (8%) | catalogued as rs546286371; called by muse, mutect2
- VIM | c.564-22G>A | Intron (SNP) | VAF 16/192 reads (8%) | catalogued as rs1251391562; called by muse, mutect2
- ZFAND2B | c.589-32C>T | Intron (SNP) | VAF 163/563 reads (29%) | called by muse, mutect2, varscan2
